Somatic mutation profile of tumor specimen TARGET-10-PAPCJR-09A (aliquot TARGET-10-PAPCJR-09A-01D) from TARGET case TARGET-10-PAPCJR, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,028 days).
Specimen TARGET-10-PAPCJR-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59b2398c-dab1-46eb-b8e1-6b0c24376953.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPCJR-14A (Bone Marrow Normal), aliquot TARGET-10-PAPCJR-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06d6d75e-4ecb-413f-9701-a0051ae0821b

The open-access MAF lists 31 somatic variants for this specimen: 19 protein-altering or splice-affecting, 3 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, Intron 3, RNA 2, 3'Flank 2, Nonsense Mutation 2, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAD11 | c.301G>A p.V101I | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as rs200038472; called by muse, mutect2, varscan2
- DNAJC6 | c.2360C>G p.S787C | Missense Mutation (SNP) | VAF 50/167 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.141); catalogued as rs947409137, COSV54779273; called by muse, mutect2, varscan2
- ESPNL | c.1966C>T p.R656W | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770071012, COSV99066737; called by muse, varscan2
- GOLGB1 | c.8350C>T p.L2784F | Missense Mutation (SNP) | VAF 58/223 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.976); catalogued as COSV61466387; called by muse, mutect2, varscan2
- GRIK3 | c.2020G>C p.D674H | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66139388; called by muse, mutect2
- IRF2BP2 | c.1720A>G p.I574V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100784308; called by muse, mutect2, varscan2
- MROH2B | c.4307C>G p.S1436* | Nonsense Mutation (SNP) | VAF 29/106 reads (27%) | catalogued as COSV68182690; called by muse, mutect2, varscan2
- NSD2 | c.3373G>C p.D1125H | Missense Mutation (SNP) | VAF 39/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56386535; called by muse, mutect2, varscan2
- PKHD1 | c.8887G>A p.V2963I | Missense Mutation (SNP) | VAF 13/172 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs749794881, COSV100582295, COSV100582364; ClinVar: uncertain significance; called by muse, mutect2
- RASGEF1B | c.251G>T p.C84F | Missense Mutation (SNP) | VAF 53/156 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.134); catalogued as rs1215536483; called by muse, mutect2, varscan2
- AFP | c.1115G>C p.R372T | Missense Mutation (SNP) | VAF 8/170 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2
- ATP8B1 | c.2767G>C p.D923H | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- BDNF | c.700G>T p.D234Y | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BEND5 | c.37T>A p.C13S | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.587); called by muse, mutect2, varscan2
- DDX60 | c.1558G>C p.D520H | Missense Mutation (SNP) | VAF 56/211 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.546); called by muse, mutect2, varscan2
- DNAAF1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, varscan2
- KATNIP | c.1235G>C p.G412A | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.31); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- REV3L | c.4307C>G p.S1436* | Nonsense Mutation (SNP) | VAF 64/226 reads (28%) | called by muse, mutect2, varscan2
- SLC12A7 | c.2670G>C p.Q890H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2
- C4orf54 | c.2958C>T p.I986= | Silent (SNP) | VAF 15/74 reads (20%) | called by muse, mutect2, varscan2
- IL18RAP | c.1233C>T p.F411= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as rs140183707; called by muse, mutect2, varscan2
- SOX9 | c.27G>A p.K9= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs747794183; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AC106741.1 | c.*7G>T | 3'UTR (SNP) | VAF 40/123 reads (33%) | called by muse, mutect2, varscan2
- AC110373.1 | n.1821C>T | RNA (SNP) | VAF 7/99 reads (7%) | catalogued as rs1052121290; called by muse, mutect2
- GRIK2 | c.2563-4314G>C | Intron (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- IGKV2D-29 | chr2:89948269 ins C | 3'Flank (INS) | VAF 35/70 reads (50%) | called by mutect2, pindel, varscan2
- LINC00470 | n.1361-2570G>C | Intron (SNP) | VAF 8/95 reads (8%) | called by muse, mutect2
- LINC02817 | n.303C>T | RNA (SNP) | VAF 5/83 reads (6%) | called by muse, mutect2
- NDUFS8 | c.372+19C>T | Intron (SNP) | VAF 13/67 reads (19%) | catalogued as rs746762147; called by muse, varscan2
- NPY4R | c.-39C>T | 5'UTR (SNP) | VAF 12/110 reads (11%) | catalogued as rs782215421; called by muse, mutect2
- RN7SL211P | chr2:64904456 G>A | 3'Flank (SNP) | VAF 10/94 reads (11%) | called by muse, mutect2
